Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4886, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4886-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN
NUCLEAR GRADE 3

(3.7 CM).

TUMOR CONFINED TO THE KIDNEY.

Focal granulomatous inflammation. (See comment)

Ureteral and renal vein margins, no tumor present.

COMMENT

There is an unusual granulomatous reaction/inflammation focally at the interface between the tumor and uninvolved renal parenchyma associated with fibrosis and chronic inflammation. No microorganisms were identified on AFB and GMS stains.

GROSS DESCRIPTION

(A) LEFT KIDNEY - A left kidney with surrounding perinephric fat measuring overall 14.5 x 9.5 x 5.0 cm. The kidney (10.0 x 6.0 x 3.0 cm) contains a yellow variegated, red well-circumscribed mass (3.7 x 3.5 x 3.0 cm) located in the mid pole of the kidney. The mass is confined to the kidney, has a rim of renal parenchyma pushing against the perinephric fat. There is focal area of possible renal sinus invasion. The renal vein is not involved by tumor. The remainder of the renal parenchyma appears unremarkable.

SECTION CODE: A1, hilar structures; A2-A4, tumor to renal sinus; A5, tumor to perinephric fat; A6, perinephric fat; A7, tumor with rim of normal kidney parenchyma; A8, tumor with possible invasion to renal sinus; A9, uninvolved renal parenchyma.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file 03a9d3e9-d3e3-4e2f-93fe-8423812f1426 (TCGA-CJ-4886.E47FCE98-74C9-43B0-9805-B4D0C44A9D1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).